Surgical pathology report (de-identified scan), TCGA case TCGA-BP-5000, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site MSKCC, specimen TCGA-BP-5000-01A (Primary Tumor).

[page 1 of 2]
Accession #:

Date of Procedure:

Date of Receipt:

Date of Report:

Account #:

Billing Type:

Additional Copy to:

Ref. Source:

Clinical Diagnosis & History:

Left renal mass.

TCGA - BP - 5000

Specimens Submitted:

1: KIDNEY, LEFT, PARTIAL NEPHRECTOMY

DIAGNOSIS:

1. KIDNEY, LEFT, PARTIAL NEPHRECTOMY

Tumor Type:

Renal cell carcinoma - Conventional (clear cell) type

Fuhrman Nuclear Grade:

Nuclear grade III/IV

Tumor Size:

Greatest diameter is 5.4 cm.

Local Invasion (for renal cortical types):

Not identified

Renal Vein Invasion:

Not identified

Small vessel angiolymphatic invasion also not identified

Surgical Margins:

Free of tumor

Non-Neoplastic Kidney:

Compression-related changes

Adrenal Gland:

Not identified

Lymph Nodes:

Not identified

Staging for renal cell carcinoma/oncocytoma:

pT1 Tumor $\leq$ 7.0 cm in greatest dimension limited to the kidney

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[page 2 of 2]
Special Studies:

Result	Special Stain	Comment
	RECUT	
	RECUT	

Gross Description:

1). The specimen is received fresh for frozen section consultation labeled "Left renal tumor, stitch marks deep margin". It consists of a 7 x 5.5 x 5.0 cm segment of renal parenchyma with attached fat measuring 12.5 x 7 x 4 cm. There is a suture marking the deep margin of the specimen. The surface is inked black. The capsular surface is inked blue. On cut section, there is a 5.4 x 5.0 x 4.9 cm apparently encapsulated, hemorrhagic, yellow-tan tumor with diffuse areas of scarring and septated appearance. It is located 0.1 cm from the black inked surface and abuts the capsule but does not grossly extend through it. There is a thin rim of residual renal parenchyma surrounding the tumor, which is brown-tan and grossly unremarkable. Representative section of the tumor is submitted for frozen section consultation. Tissue is given to TPS. Representative sections are submitted.

Summary of sections:

FSC – frozen section control

TM-tumor with margin

TC-tumor with capsule

TN-tumor with rim of normal kidney parenchyma

T-tumor

Summary of Sections:

Part 1: KIDNEY, LEFT, PARTIAL NEPHRECTOMY

Block	Sect. Site	PCs
1	fsc	1
2	tc	2
2	tm	2
2	tn	2

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: RENAL CELL CARCINOMA. THE MARGIN (INKED) IS FREE OF TUMOR.
PERMANENT DIAGNOSIS: SAME

Source: NCI Genomic Data Commons file 5081ecfe-bbda-46ed-8dc3-d58ec1d7cafb (TCGA-BP-5000.60CBCADE-ADED-404E-AFE4-9FBD83AB5499.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).